Gene-level copy-number profile of tumor specimen C3L-06982-55 from CPTAC case C3L-06982, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 22.7 years (8,279 days).
Specimen C3L-06982-55: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f933fa61-81de-4855-9f14-3372a49ef4e6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06982-50 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/3e9dfa16-c48a-45cc-b34b-59141d18a66a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 195; copy number 2: 58,077; copy number 3: 110; copy number 4: 3.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:27,042,364–27,086,403, 7 genes: AGBL5, AGBL5-AS1, AC013472.2, AGBL5-IT1, AC013403.2, OST4, EMILIN1.
- chr2:180,872,867–180,873,414, 1 gene (within-gene range 0–2): FTH1P20.
- chr11:1,991,096–2,001,470, 5 genes: LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr12:125,858,132–125,880,724, 2 genes: AC005252.4, AC005252.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 195. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
